Somatic mutation profile of tumor specimen TCGA-GI-A2C8-01A (aliquot TCGA-GI-A2C8-01A-11D-A16D-09) from TCGA case TCGA-GI-A2C8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.3 years (23,103 days).
Specimen TCGA-GI-A2C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69ca2b97-43dd-465a-84f3-ab2265dbd562.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GI-A2C8-11A (Solid Tissue Normal), aliquot TCGA-GI-A2C8-11A-22D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8be97d7-c1bd-43d2-b046-5fadd89f7e2c

The open-access MAF lists 115 somatic variants for this specimen: 91 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 84, Silent 24, Nonsense Mutation 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52982278; called by muse, mutect2, varscan2
- ADAM19 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV57439428; called by muse, mutect2, varscan2
- ADAMTS19 | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs571986172, COSV50799260; called by muse, mutect2, varscan2
- ADAMTS2 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473580610, COSV52380549; called by muse, mutect2, varscan2
- ADGRG7 | c.1637T>A p.L546H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56301433; called by muse, mutect2, varscan2
- ADM5 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV54922275; called by muse, mutect2, varscan2
- AFF1 | c.1445A>G p.D482G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100320906; called by muse, mutect2, varscan2
- ARHGEF6 | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV51690786, COSV51696022; called by muse, mutect2, varscan2
- BEND2 | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.665); catalogued as COSV66217334; called by muse, mutect2, varscan2
- BZW2 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV51757741, COSV99334599; called by muse, mutect2, varscan2
- CACNA1F | c.2978T>A p.V993E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59907077; called by muse, mutect2, varscan2
- CARMIL1 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); catalogued as rs767321872, COSV61523996; called by muse, mutect2, varscan2
- CD163 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs181334925, COSV63131936, COSV63133746; called by muse, mutect2, varscan2
- CD96 | c.1025G>T p.S342I (on ENST00000283285 / NM_198196.3; = p.S326I on NM_005816.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV51923156; called by muse, mutect2, varscan2
- CDH1 | c.1226G>T p.W409L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55734479, COSV55741113; called by muse, mutect2, varscan2
- CDH6 | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV54078599; called by muse, mutect2, varscan2
- CFAP65 | c.4658C>G p.T1553S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV58566360; called by muse, mutect2, varscan2
- CHD6 | c.1461G>C p.E487D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58562508; called by muse, mutect2, varscan2
- CNKSR2 | c.1772G>T p.W591L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268181; called by muse, mutect2
- CSMD3 | c.7550-2A>C p.X2517_splice (on ENST00000297405 / NM_001363185.1; = p.X2413_splice on NM_052900.3) | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99841695; called by muse, mutect2
- DDX60L | c.3500A>T p.K1167I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV52722091; called by muse, mutect2, varscan2
- DGCR2 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758777267, COSV54222464; called by muse, mutect2, varscan2
- DNAH11 | c.7549A>G p.T2517A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV60981945; called by muse, mutect2, varscan2
- DPF3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.973); catalogued as rs369169805; called by muse, mutect2, varscan2
- EPHA6 | c.1823A>C p.H608P | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV101064547, COSV67597166; called by muse, mutect2, varscan2
- FAM160B1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV65089771; called by muse, mutect2, varscan2
- FAT1 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs765342648, COSV71675921; called by muse, mutect2, varscan2
- FER1L6 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766353103, COSV67550997; called by muse, mutect2, varscan2
- FGFR2 | c.1632C>G p.H544Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60655021, COSV60660044; called by muse, mutect2, varscan2
- GREB1 | c.2146C>T p.H716Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs770801145, COSV99303404; called by muse, mutect2
- GRIA3 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52080709; called by muse, mutect2, varscan2
- GUCY2C | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs771612876, COSV53792739; called by muse, mutect2, varscan2
- HECTD1 | c.4153A>C p.S1385R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.363); catalogued as COSV67949210; called by muse, mutect2, varscan2
- HECW1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV67820685; called by muse, mutect2, varscan2
- IFTAP | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV100531276; called by muse, mutect2
- IL11RA | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV52405753; called by muse, mutect2, varscan2
- IL6ST | c.1520C>G p.P507R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as COSV61142991; called by muse, mutect2, varscan2
- IPO5 | c.2986T>C p.W996R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55160013; called by muse, mutect2, varscan2
- KLHL25 | c.1319T>G p.V440G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs751933815, COSV61996541; called by muse, mutect2, varscan2
- KNG1 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV53981066; called by muse, mutect2, varscan2
- KRT32 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV56786704, COSV56788262; called by muse, mutect2, varscan2
- LAMB1 | c.4280G>A p.G1427E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774611936, COSV55970320; called by muse, mutect2, varscan2
- LCE4A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV59267351; called by muse, mutect2, varscan2
- LRP1 | c.5022G>C p.W1674C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99676610; called by muse, mutect2
- LRP6 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143966208, COSV53784596; called by muse, mutect2, varscan2
- LRRTM4 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69142358; called by muse, mutect2, varscan2
- MAGI2 | c.3409T>A p.Y1137N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.853); catalogued as COSV62699361; called by muse, mutect2, varscan2
- MARK1 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV65071483, COSV65072438; called by muse, mutect2, varscan2
- MDM4 | c.394A>T p.S132C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV65796804; called by muse, mutect2, varscan2
- MOXD1 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60943101, COSV60949287; called by muse, mutect2, varscan2
- MPHOSPH10 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.061); catalogued as COSV99731219; called by muse, mutect2, varscan2
- MSRB3 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100378119; called by muse, mutect2
- NDUFV1 | c.123T>G p.I41M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV59596691; called by muse, mutect2, varscan2
- NLGN4X | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52021976; called by muse, mutect2, varscan2
- NUP160 | c.3530T>A p.I1177N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1425938957, COSV101021566; called by muse, mutect2
- OTOF | c.3893T>G p.V1298G (on ENST00000272371 / NM_194248.3; = p.V531G on NM_004802.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV55520232; called by muse, mutect2, varscan2
- PCDHGA1 | c.224T>C p.F75S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65299836; called by muse, mutect2, varscan2
- PDK4 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778644301, COSV99138905; called by muse, mutect2, varscan2
- PHF8 | c.2854A>T p.T952S (on ENST00000357988 / NM_001184896.1; = p.T916S on NM_015107.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV57688058; called by muse, mutect2, varscan2
- PHKA2 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66056390; called by muse, mutect2, varscan2
- PLA2R1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1558948988, COSV51784407, COSV99323282; called by muse, mutect2
- PLCH1 | c.2234C>T p.P745L (on ENST00000340059 / NM_001130960.2; = p.P757L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58210350; called by muse, mutect2, varscan2
- PLEKHM3 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.058); catalogued as rs1238493539, COSV66818797; called by muse, mutect2
- POGZ | c.3618G>C p.E1206D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV51853313; called by muse, mutect2
- PPP4R3B | c.1766G>A p.C589Y (on ENST00000616407 / NM_001122964.3; = p.G504D on NM_020463.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55409324; called by muse, mutect2, varscan2
- PRDM10 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.012); catalogued as COSV58805349; called by muse, mutect2, varscan2
- RAP2B | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60257513; called by muse, mutect2, varscan2
- RNASE9 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs779466707, COSV58881260; called by muse, mutect2, varscan2
- RYR3 | c.5599C>T p.R1867C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566906663, COSV66808853; called by muse, mutect2, varscan2
- SCML2 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52625100; called by muse, mutect2, varscan2
- SEMA3C | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99543465; called by muse, mutect2
- SEMA4F | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs201138724; called by mutect2, varscan2
- SLC24A4 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV54121712; called by muse, mutect2
- SNX7 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.024); catalogued as COSV60268192, COSV60272154; called by muse, mutect2, varscan2
- SRM | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV65385027; called by muse, mutect2, varscan2
- TMEM168 | c.1715T>A p.I572K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs759754469; called by mutect2, varscan2
- TNR | c.3728G>A p.R1243K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557866367, COSV99690657; called by muse, mutect2
- TTC37 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs868011508, COSV100706763; called by muse, mutect2, varscan2
- TTN | c.63745A>G p.K21249E (on ENST00000591111; = p.K13825E on NM_003319.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | PolyPhen probably damaging (0.994); catalogued as COSV60354731; called by muse, mutect2, varscan2
- TTN | c.47055C>A p.N15685K (on ENST00000591111; = p.N8261K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | PolyPhen benign (0.23); catalogued as rs1179567067, COSV60354761; called by muse, mutect2, varscan2
- TTPA | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52648462; called by muse, mutect2, varscan2
- USP3 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 41/149 reads (28%) | catalogued as COSV51429720, COSV99165649; called by muse, mutect2, varscan2
- USP39 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV60383654; called by muse, mutect2, varscan2
- USP48 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57614861; called by muse, mutect2, varscan2
- VIRMA | c.4742G>T p.G1581V | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99888970; called by muse, mutect2
- VPS26B | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV55546631; called by muse, mutect2, varscan2
- ZC3H13 | c.58A>C p.T20P | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.69); catalogued as COSV54463388; called by muse, mutect2, varscan2
- ZNF333 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52888535; called by muse, mutect2, varscan2
- ZNF333 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs767773638, COSV52888545; called by muse, mutect2, varscan2
- ZNF431 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV60675519; called by muse, mutect2, varscan2
- ZNF670 | c.761_773del p.E254Vfs*27 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- ABCA6 | c.4107G>A p.L1369= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52645038; called by muse, mutect2, varscan2
- ASIC2 | c.1533C>G p.A511= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV99860673; called by muse, mutect2, varscan2
- ASPM | c.2316G>A p.L772= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99660827; called by muse, mutect2
- BTNL3 | c.678G>A p.T226= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs371607835, COSV61565906; called by muse, mutect2, varscan2
- BVES | c.129G>T p.L43= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58950029; called by muse, mutect2, varscan2
- C3AR1 | c.471G>T p.V157= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV50824943; called by muse, mutect2, varscan2
- CHD5 | c.3882G>A p.V1294= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99314400; called by muse, mutect2
- DNAH17 | c.810C>T p.N270= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs755284588, COSV67756227; called by muse, mutect2, varscan2
- DOCK10 | c.1203C>A p.L401= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV51428043; called by muse, mutect2, varscan2
- HMCN1 | c.7179T>C p.P2393= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV54942350; called by muse, mutect2, varscan2
- HMGCR | c.357A>G p.T119= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs746136156, COSV55318103; called by muse, mutect2, varscan2
- ITSN1 | c.4974C>G p.V1658= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV67156773, COSV67157652; called by muse, mutect2, varscan2
- LRBA | c.4917G>A p.E1639= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV63965130; called by muse, mutect2, varscan2
- MEI1 | c.2949C>T p.S983= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1477987491, COSV55907993; called by muse, mutect2, varscan2
- MSRA | c.660C>T p.C220= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs760395850, COSV57811637; called by muse, mutect2, varscan2
- NXF1 | c.1719A>G p.A573= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV53676769; called by muse, mutect2, varscan2
- OBSCN | c.12429A>T p.T4143= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52830650; called by muse, mutect2, varscan2
- OR52K2 | c.282A>T p.I94= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV57834738, COSV57835869; called by muse, mutect2, varscan2
- ROS1 | c.6204C>G p.V2068= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV63861759; called by muse, mutect2, varscan2
- SCN7A | c.1608T>A p.L536= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV101313314; called by muse, mutect2
- SSTR5 | c.267C>T p.Y89= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53513549; called by muse, mutect2, varscan2
- USP3 | c.930C>T p.V310= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV51429711; called by muse, mutect2, varscan2
- VPS26B | c.243G>T p.G81= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV55546642; called by muse, mutect2, varscan2
- WDR59 | c.1281C>G p.V427= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV50945092; called by muse, mutect2, varscan2
